Surgical pathology report (de-identified scan), TCGA case TCGA-D6-A4Z9, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-A4Z9-01A (Primary Tumor).

Department of Cancer Pathology

Gender: M

Examination result

Clinical diagnosis (suspicion) **Cancer of the tongue - left side Histopathology result: Carcinoma planoepitheliale keratodes infiltrans G2.**

Material:

1) Material: Oral cavity – tongue. Please examine the marked margin. Method of collection: Collection of specimens for laboratory examination

Histopathological Diagnosis:

**Invasive squamous carcinoma of the tongue partially keratinizing and ulcerating (G2)
Carcinoma planoepitheliale partim keratodes invasivum exulcerans (G2). Excisio completa.
All wire-marked margins free of neoplastic lesions. (8071/3**

Macroscopic description:

Surgical specimen sized 4.5 x 4 x 2cm with flat raised, ulcerated tumour sized 3.5 x 2.0 x 0.8cm.
Minimum margin at the side of the 4 wiress 1.1 cm.

Assistant:

Results of intraoperative examination:

No cancerous lesions found within the margins marked with stitches.

Assistant:

CONTACT YOUR DOCTOR WITH THIS REPORT!

ICD-0-3

Carcinoma, squamous cell, keratinizing, NOS 8071/3

Site: tongue, NOS C02.9

hw
11/5/12

ICDPA Discrepancy		
Known Malignancy History		
Qualifying Primary Tumor		

hw
11/5/12

Source: NCI Genomic Data Commons file a8db8a40-f8b6-42e3-b1ba-37cfc7592612 (TCGA-D6-A4Z9.16B5349E-DBD3-46E6-BE3E-8335FAFC578A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).